CCDI case PBCIGD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/64e05872-b87b-4df6-94b0-7d259846f6cb

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.8 years (3,933 days).

Biospecimens (3 samples)
- Sample 0DSI7K: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSI8B: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSI9W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
